Somatic mutation profile of tumor specimen TCGA-49-AARQ-01A (aliquot TCGA-49-AARQ-01A-11D-A410-08) from TCGA case TCGA-49-AARQ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 41.2 years (15,065 days).
Specimen TCGA-49-AARQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6848327-41a0-40dd-a47f-8050370ebf77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AARQ-11A (Solid Tissue Normal), aliquot TCGA-49-AARQ-11A-21D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93453505-82df-4ab7-9c06-e100156891e2

The open-access MAF lists 770 somatic variants for this specimen: 594 protein-altering or splice-affecting, 157 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 513, Silent 157, Nonsense Mutation 52, Splice Site 13, Frame Shift Del 8, RNA 7, Intron 6, Splice Region 4, Frame Shift Ins 4, 5'UTR 3, 5'Flank 2, 3'UTR 1.

Variants (750 of 770; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TBX5 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs1565923887, COSV100090639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3753T>A p.Y1251* | Nonsense Mutation (SNP) | VAF 32/114 reads (28%) | catalogued as COSV100228576; called by muse, mutect2
- AADACL2 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs759026153, COSV100735688; called by muse, mutect2, varscan2
- ABCA10 | c.2670G>T p.L890F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs1247503687, COSV99287980; called by muse, mutect2, varscan2
- ABCA13 | c.3904C>G p.L1302V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550092103, COSV101329945; called by muse, mutect2, varscan2
- ABCA13 | c.12060G>T p.K4020N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101446837; called by muse, mutect2
- ABCA6 | c.4674G>T p.Q1558H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99445923; called by muse, mutect2, varscan2
- ABHD17B | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1340875724, COSV100330096; called by muse, mutect2, varscan2
- AC011455.2 | c.1472G>C p.S491T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV99671138; called by muse, mutect2, varscan2
- AC131160.1 | c.585T>G p.Y195* | Nonsense Mutation (SNP) | VAF 84/151 reads (56%) | catalogued as COSV100226095; called by muse, mutect2, varscan2
- ACKR1 | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs745704535, COSV100929479; called by muse, mutect2, varscan2
- ACSL6 | c.1708C>A p.P570T (on ENST00000379240; = p.P595T on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99732807; called by muse, mutect2, varscan2
- ACSS3 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV99698370; called by muse, varscan2
- ACTC1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as COSV99291630; called by muse, mutect2, varscan2
- ACTL6B | c.1118T>C p.M373T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99355450; called by muse, mutect2, varscan2
- ACTRT3 | c.233G>T p.W78L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377352; called by muse, mutect2, varscan2
- ADAMTS10 | c.3203A>G p.E1068G | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1320958409, COSV99546515; called by muse, mutect2, varscan2
- ADAMTS10 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1555740195, COSV99546517; called by muse, mutect2, varscan2
- ADAMTS12 | c.4424G>T p.W1475L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361645201, COSV100710361; called by muse, mutect2, varscan2
- ADAMTS12 | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1253048572, COSV100710363; called by muse, mutect2, varscan2
- ADCY5 | c.3644C>A p.P1215H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100567375; called by muse, mutect2
- ADGRG4 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99794505; called by muse, mutect2, varscan2
- ADIPOR2 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100840036; called by muse, mutect2, varscan2
- ADRA1D | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101062912; called by muse, mutect2
- AFF2 | c.3137C>A p.A1046E | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs782193038, COSV53993050, COSV99662140; called by muse, mutect2, varscan2
- AFF2 | c.3352C>A p.L1118M | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV99662143; called by muse, mutect2, varscan2
- AGO1 | c.2431G>T p.A811S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100940768; called by muse, mutect2, varscan2
- AHNAK2 | c.15201C>A p.D5067E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100315890; called by muse, mutect2, varscan2
- AHNAK2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100315892; called by muse, mutect2
- AIM2 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV100931033; called by muse, mutect2, varscan2
- AKAP6 | c.3748A>T p.K1250* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99798722; called by muse, mutect2, varscan2
- AL136295.1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 55/360 reads (15%) | catalogued as COSV99937790, COSV99938063; called by muse, mutect2, varscan2
- ALDH1A1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99921102; called by muse, mutect2, varscan2
- ALDH1L1 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1388273620, COSV56419681; called by muse, mutect2, varscan2
- ALOX12 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277900; called by muse, mutect2, varscan2
- AMPH | c.1135-1G>T p.X379_splice | Splice Site (SNP) | VAF 6/104 reads (6%) | catalogued as COSV100341062; called by muse, mutect2
- ANGPT1 | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99862035, COSV99863128; called by muse, mutect2, varscan2
- ANK1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99224148; called by muse, mutect2
- ANK2 | c.4794G>T p.E1598D | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as COSV100000015; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4245G>T p.K1415N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99782245; called by muse, mutect2, varscan2
- ANKRD27 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV100042579, COSV100043305; called by muse, mutect2
- ANKRD6 | c.1395G>T p.M465I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.626); catalogued as COSV100329472; called by muse, mutect2, varscan2
- AP002512.3 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99687793; called by muse, mutect2, varscan2
- AP1G2 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100436582; called by muse, mutect2, varscan2
- APOB | c.10349C>T p.S3450L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99263901; called by muse, varscan2
- APOB | c.2881C>A p.Q961K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as COSV51958464, COSV99263904; called by muse, mutect2, varscan2
- ARHGAP21 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100255829; called by muse, mutect2, varscan2
- ARHGEF25 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs866129970, COSV99677578; called by muse, mutect2, varscan2
- ARID2 | c.3760A>T p.T1254S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100535497; called by muse, mutect2, varscan2
- ARL4C | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV100326784; called by muse, mutect2, varscan2
- ARMC4 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs376424270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASIC4 | c.188A>G p.H63R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100761576; called by muse, mutect2, varscan2
- ASPM | c.8987G>T p.R2996L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV104399268, COSV99659642; called by muse, mutect2, varscan2
- ASXL3 | c.6697G>C p.D2233H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99323617; called by muse, mutect2, varscan2
- ASXL3 | c.6698A>T p.D2233V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1385762135, COSV99323620; called by muse, mutect2, varscan2
- ATP12A | c.1882-2A>G p.X628_splice | Splice Site (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99517086; called by muse, mutect2, varscan2
- ATP9A | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV58768340; called by muse, mutect2, varscan2
- ATR | c.3625G>T p.G1209C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250182269, COSV100637726; called by muse, mutect2, varscan2
- ATRNL1 | c.2533G>T p.G845W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369493; called by muse, mutect2, varscan2
- AZGP1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.044); catalogued as COSV99447694; called by muse, mutect2, varscan2
- AZI2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99843475; called by muse, mutect2, varscan2
- BAG5 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54572636; called by muse, mutect2, varscan2
- BARHL1 | c.220T>A p.L74M | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV55038575, COSV99707462; called by muse, mutect2, varscan2
- BCORL1 | c.1296A>T p.K432N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99498628; called by muse, mutect2, varscan2
- BICC1 | c.2031G>T p.L677F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1248657887, COSV99570252; called by muse, mutect2, varscan2
- BMP1 | c.2813A>T p.Y938F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100114607; called by muse, mutect2, varscan2
- BMP7 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV101215578, COSV67779870; called by muse, mutect2
- BRD8 | c.2630C>A p.S877Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs1355669548, COSV99136636; called by muse, mutect2, varscan2
- BRDT | c.330G>A p.K110= | Splice Region (SNP) | VAF 41/88 reads (47%) | catalogued as COSV100740299, COSV61771071; called by muse, mutect2, varscan2
- BRSK1 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1164458618, COSV100473716; called by muse, mutect2, varscan2
- BRWD3 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100955698; called by muse, mutect2, varscan2
- CACNA2D1 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.632); catalogued as COSV100666089; called by muse, mutect2, varscan2
- CADPS | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV99336205; called by muse, mutect2, varscan2
- CAMTA1 | c.2561C>G p.A854G | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV100346681, COSV57899338; called by muse, mutect2, varscan2
- CAPN6 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100136728; called by muse, mutect2, varscan2
- CAPRIN1 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.056); catalogued as COSV100403555; called by muse, mutect2, varscan2
- CAPRIN2 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195425; called by muse, mutect2, varscan2
- CARMIL3 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.36); catalogued as rs774706113, COSV100549297; called by muse, mutect2, varscan2
- CCDC105 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs369331488, COSV99479893; called by muse, mutect2, varscan2
- CCDC180 | c.-84G>A | Splice Region (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100826585; called by muse, mutect2, varscan2
- CCDC197 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 27/46 reads (59%) | catalogued as rs192272134, COSV100113609, COSV58939762; called by muse, mutect2, varscan2
- CCDC9 | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.818); catalogued as rs1330213335, COSV99699556; called by muse, mutect2, varscan2
- CCER1 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV62647306; called by muse, mutect2, varscan2
- CCNA1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753604464, COSV55225295; called by muse, mutect2, varscan2
- CD200R1 | c.947G>T p.S316I (on ENST00000471858 / NM_170780.3; = p.S339I on NM_138806.4) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99866787; called by muse, mutect2, varscan2
- CD79B | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV99137608; called by muse, mutect2, varscan2
- CD83 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100997725; called by muse, mutect2, varscan2
- CDCA7L | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301630062, COSV60966655, COSV60982391; called by muse, mutect2, varscan2
- CDH12 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as rs1335363693, COSV101201664; called by muse, mutect2, varscan2
- CDH12 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101201665; called by muse, mutect2, varscan2
- CDO1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1479113682, COSV99164754; called by muse, mutect2, varscan2
- CEP95 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV101616294; called by muse, mutect2, varscan2
- CERKL | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1457832711, COSV100183211; called by muse, mutect2, varscan2
- CFAP43 | c.3085G>T p.A1029S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.262); catalogued as rs759954879, COSV53377720, COSV99530439; called by muse, mutect2, varscan2
- CFHR5 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201808624, COSV99888045; called by muse, mutect2, varscan2
- CHAC1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as rs1440627484, COSV101471060; called by muse, mutect2
- CHAF1A | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV100010879; called by muse, varscan2
- CHGB | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV100972920; called by muse, mutect2, varscan2
- CHPF | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV99704708; called by muse, mutect2, varscan2
- CLCA1 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.315); catalogued as COSV52325037, COSV99321952; called by muse, mutect2, varscan2
- CLIP2 | c.2880G>T p.L960= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99791048; called by muse, mutect2
- CLRN2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101492684; called by muse, mutect2, varscan2
- CLSPN | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV99230371; called by muse, mutect2
- CLSTN1 | c.1804A>T p.M602L (on ENST00000377298 / NM_001009566.3; = p.M592L on NM_014944.4) | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100790474; called by muse, mutect2, varscan2
- CMC4 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100749851; called by muse, mutect2, varscan2
- CNKSR2 | c.935G>T p.R312I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99667496; called by muse, mutect2, varscan2
- CNTNAP2 | c.2120G>T p.W707L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62182918; called by muse, mutect2, varscan2
- CNTNAP2 | c.3926C>G p.A1309G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV62186854; called by muse, mutect2
- COG3 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.804); catalogued as COSV100596395; called by muse, mutect2, varscan2
- COL15A1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as COSV100897457; called by muse, mutect2
- COL21A1 | c.2701C>A p.P901T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs1284288830, COSV99777619; called by muse, mutect2, varscan2
- COL4A1 | c.3815G>T p.G1272V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65431001; called by muse, varscan2
- COL4A1 | c.3814G>T p.G1272C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65424087; called by muse, mutect2, varscan2
- COL4A3 | c.4946C>T p.T1649I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101170001; called by muse, mutect2, varscan2
- COL4A4 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs560819344, COSV100306326; called by muse, mutect2, varscan2
- COL4A6 | c.2311G>C p.G771R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563464, COSV57866793; called by muse, mutect2, varscan2
- COL6A2 | c.1609-2A>T p.X537_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56009016; called by muse, mutect2, varscan2
- CPAMD8 | c.3184A>T p.S1062C (on ENST00000651564; = p.S1015C on NM_015692.5) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101488419; called by muse, mutect2, varscan2
- CSMD1 | c.4456C>A p.P1486T (on ENST00000520002; = p.P1485T on NM_033225.6) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100144502; called by muse, mutect2, varscan2
- CSMD2 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99586671; called by muse, mutect2, varscan2
- CST8 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV99849883; called by muse, mutect2, varscan2
- CSTF3 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV100123783; called by muse, mutect2, varscan2
- CYP11B2 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100010735, COSV59994248; called by muse, mutect2, varscan2
- CYP26B1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs371681434; called by muse, mutect2
- CYP27A1 | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as COSV99298360; called by muse, mutect2, varscan2
- DACH2 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100912624; called by muse, mutect2, varscan2
- DCAF12L2 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100758476, COSV63584129; called by muse, mutect2, varscan2
- DCDC1 | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100662801; called by muse, mutect2, varscan2
- DCLK2 | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99651486; called by muse, mutect2, varscan2
- DCT | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100986119; called by muse, mutect2, varscan2
- DDN | c.1710C>G p.H570Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as rs778848522, COSV101373594, COSV70404224; called by muse, mutect2, varscan2
- DDX19A | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100156179; called by muse, mutect2, varscan2
- DEPDC1B | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99409429; called by muse, mutect2, varscan2
- DGKI | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as rs267601309, COSV99932685; called by muse, mutect2, varscan2
- DGKK | c.3803G>A p.R1268K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV101052897; called by muse, mutect2, varscan2
- DHX8 | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99291960; called by muse, mutect2, varscan2
- DLAT | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV99734454; called by muse, mutect2, varscan2
- DLC1 | c.1585G>T p.D529Y (on ENST00000276297 / NM_001348081.2; = p.D92Y on NM_006094.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1411474941, COSV99361420; called by muse, mutect2, varscan2
- DLG2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs915016253, COSV99712956; called by muse, mutect2, varscan2
- DLGAP2 | c.540C>A p.H180Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs781064765, COSV101421115; called by muse, mutect2, varscan2
- DNAH10 | c.3013C>A p.P1005T (on ENST00000409039; = p.P944T on NM_207437.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV101292026; called by muse, mutect2, varscan2
- DNAH9 | c.10252C>T p.P3418S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1194750601, COSV99304412; called by muse, mutect2, varscan2
- DNAJC3 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100953289; called by muse, mutect2, varscan2
- DNAJC6 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1461001065, COSV99674120; called by muse, mutect2
- DPPA2 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs773197973, COSV101524738, COSV72118125, COSV72118171; called by muse, mutect2, varscan2
- DRAP1 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs777331540, COSV100437047, COSV56988102; called by muse, mutect2, varscan2
- DRC3 | c.781A>T p.N261Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV100572632; called by muse, mutect2, varscan2
- DST | c.20089C>T p.Q6697* (on ENST00000361203 / NM_001374722.1; = p.Q4394* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99751731; called by muse, mutect2, varscan2
- EBAG9 | c.497C>G p.A166G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1255174109, COSV100520762; called by muse, mutect2, varscan2
- EDIL3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1187468940, COSV99675002; called by muse, mutect2, varscan2
- EFCAB13 | c.2806C>A p.Q936K | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100516364; called by muse, mutect2, varscan2
- EGLN3 | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99164293; called by muse, mutect2, varscan2
- EHBP1 | c.2749G>T p.E917* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99860161; called by muse, mutect2, varscan2
- EIF2D | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV99662568; called by muse, mutect2, varscan2
- ELFN2 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101297482; called by muse, mutect2, varscan2
- ELOA2 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99796036; called by muse, mutect2, varscan2
- ENOX2 | c.377G>A p.G126E (on ENST00000338144 / NM_001382520.1; = p.G97E on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs770577864, COSV100583836; called by muse, mutect2, varscan2
- EP300 | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as rs1180296301, COSV99607521, COSV99607651; called by muse, mutect2, varscan2
- EPB41L3 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100548244, COSV59463609; called by muse, mutect2, varscan2
- EPHA3 | c.971G>C p.R324P | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV100343306; called by muse, mutect2, varscan2
- EPHA7 | c.1275C>A p.S425R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100993326; called by muse, mutect2, varscan2
- EPS8L3 | c.1520T>A p.L507Q (on ENST00000361965 / NM_133181.4; = p.L477Q on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100719669; called by muse, mutect2, varscan2
- EPYC | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99664505; called by muse, mutect2, varscan2
- EVC | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1342618312, COSV99381229; called by muse, mutect2, varscan2
- EVI2B | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.124); catalogued as rs746629693, COSV100445396; called by muse, mutect2, varscan2
- EVX2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100420561; called by muse, mutect2, varscan2
- F13A1 | c.947G>T p.W316L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99342318; called by muse, mutect2, varscan2
- F2RL2 | c.1061A>G p.D354G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56970831, COSV99166754; called by muse, mutect2, varscan2
- FAM135B | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99419661; called by muse, mutect2, varscan2
- FAM163A | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100522925; called by muse, mutect2, varscan2
- FAM214B | c.440del p.P147Hfs*50 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV59715297; called by mutect2, pindel, varscan2
- FAM217B | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs570477685, COSV100674420, COSV62563924; called by muse, mutect2, varscan2
- FANCE | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100003199; called by muse, mutect2, varscan2
- FASTK | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV99879567; called by muse, mutect2
- FAT4 | c.3910G>T p.D1304Y | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV67883495, COSV67886781; called by muse, mutect2, varscan2
- FBN2 | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1284853055, COSV99325344; called by muse, mutect2, varscan2
- FBN3 | c.6628G>T p.E2210* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as rs780169597, COSV99560018; called by muse, mutect2, varscan2
- FBXO21 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100401619; called by muse, mutect2, varscan2
- FBXO24 | c.445C>T p.L149F (on ENST00000241071 / NM_033506.3; = p.L187F on NM_012172.5) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53827916, COSV99575017; called by muse, mutect2, varscan2
- FCRL4 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99619353; called by muse, mutect2, varscan2
- FCRL5 | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV100708584; called by muse, mutect2, varscan2
- FCRL5 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as rs753400847, COSV100708750, COSV62519780; called by muse, mutect2, varscan2
- FHL5 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100459179; called by muse, mutect2, varscan2
- FKBP6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99333742; called by muse, mutect2, varscan2
- FLG | c.3085C>A p.P1029T | Missense Mutation (SNP) | VAF 264/517 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs746336266, COSV100910635, COSV64239203; called by muse, mutect2, varscan2
- FLNA | c.5874G>C p.M1958I (on ENST00000369850 / NM_001110556.2; = p.M1950I on NM_001456.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100774330, COSV61042951; called by muse, mutect2, varscan2
- FLRT3 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963663, COSV99427843; called by muse, mutect2, varscan2
- FLT1 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV56720299, COSV99148736; called by muse, mutect2, varscan2
- FMN2 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV100143184; called by muse, mutect2, varscan2
- FNDC7 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV99600946; called by muse, mutect2, varscan2
- FOXC1 | c.334T>A p.F112I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101083228; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1898C>A p.P633H | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100435774; called by muse, mutect2, varscan2
- GAB3 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs1557256511, COSV100850423; called by muse, mutect2, varscan2
- GABRB1 | c.1231C>G p.R411G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV54986839, COSV54988273, COSV55000495; called by muse, mutect2, varscan2
- GABRG1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.911); catalogued as rs1334218998, COSV99777487; called by muse, mutect2, varscan2
- GDPD2 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100978555; called by muse, mutect2, varscan2
- GDPD4 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs755571919, COSV100265073; called by muse, mutect2, varscan2
- GFOD1 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101014968; called by muse, mutect2, varscan2
- GINM1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100805285; called by muse, mutect2, varscan2
- GJC2 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as rs373075457, COSV100812882; called by muse, mutect2, varscan2
- GLA | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023798, COSV99516199; called by muse, mutect2, varscan2
- GLI3 | c.849G>T p.R283S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101229742; called by muse, mutect2, varscan2
- GLUL | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100091853; called by muse, mutect2, varscan2
- GON4L | c.5050C>T p.Q1684* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV55195402; called by muse, varscan2
- GON4L | c.4737C>G p.I1579M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1469777297, COSV99673501; called by muse, mutect2, varscan2
- GON4L | c.2996C>T p.S999L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs866287343, COSV99673503; called by muse, mutect2, varscan2
- GPA33 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900940; called by muse, mutect2, varscan2
- GPC5 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100992927; called by muse, mutect2, varscan2
- GPR142 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100170686; called by muse, mutect2, varscan2
- GPR173 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as COSV100212065; called by muse, varscan2
- GPR4 | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100546927; called by muse, mutect2, varscan2
- GPR52 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99268148; called by muse, mutect2, varscan2
- GPR85 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV51784229, COSV51785392, COSV99775076; called by muse, mutect2, varscan2
- GPR85 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV99775078; called by muse, mutect2, varscan2
- GPR87 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.235); catalogued as rs764492925, COSV53463046; called by muse, mutect2, varscan2
- GPRASP1 | c.3852A>T p.L1284F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850917; called by muse, mutect2, varscan2
- GPRASP2 | c.2418G>C p.E806D | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV100176571, COSV59991045; called by muse, mutect2, varscan2
- GRM6 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as COSV99179465; called by muse, mutect2, varscan2
- GTPBP1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV99322958; called by muse, mutect2
- H2AC12 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.3); catalogued as rs150434841; called by muse, mutect2, varscan2
- H2BC10 | c.139A>T p.K47* | Nonsense Mutation (SNP) | VAF 48/220 reads (22%) | catalogued as COSV100010023; called by muse, mutect2, varscan2
- HAP1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100169430; called by muse, mutect2
- HCN2 | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV52115447; called by muse, mutect2, varscan2
- HDGFL1 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV100014503; called by muse, mutect2, varscan2
- HEATR5B | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761647071, COSV99248440; called by muse, mutect2, varscan2
- HECTD4 | c.8537A>T p.D2846V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101106799; called by muse, mutect2, varscan2
- HERC2 | c.13004A>T p.Y4335F | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.66); catalogued as COSV99871383; called by muse, mutect2, varscan2
- HERC6 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as rs1239209841, COSV99910458; called by muse, mutect2, varscan2
- HIF1A | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100048521, COSV60188726; called by muse, mutect2, varscan2
- HINT2 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99427859; called by muse, mutect2
- HNRNPC | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV100192896; called by muse, mutect2, varscan2
- HOXA13 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1304431464, COSV99763493; called by muse, mutect2, varscan2
- HPX | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV99793213; called by muse, mutect2, varscan2
- HSPA1A | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs1462251279, COSV100989335; called by muse, mutect2, varscan2
- HTATSF1 | c.1952C>A p.A651E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99511414; called by muse, mutect2, varscan2
- HTT | c.5507G>A p.W1836* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100750464; called by muse, mutect2, varscan2
- IGF2R | c.5263C>T p.H1755Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100806967; called by muse, mutect2, varscan2
- IGFBP1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99298646; called by muse, mutect2, varscan2
- IGFBP3 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99298227; called by muse, mutect2, varscan2
- IGFBPL1 | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100890741; called by muse, mutect2, varscan2
- IGHM | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs547967601; called by muse, mutect2, varscan2
- IGHV3-33 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1555493766; called by muse, mutect2
- IGSF11 | c.106C>T p.R36W (on ENST00000393775 / NM_001015887.3; = p.R35W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765935199, COSV61169579, COSV61174748; called by muse, mutect2, varscan2
- IL10RA | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV99922895; called by muse, mutect2, varscan2
- IL13RA1 | c.1192-2A>G p.X398_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100861514; called by muse, mutect2, varscan2
- IL3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57309399, COSV99735293; called by muse, mutect2
- IL4R | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1352293184, COSV99404746; called by muse, mutect2, varscan2
- IMPDH1 | c.853A>G p.M285V (on ENST00000470772 / NM_001142573.2; = p.M371V on NM_000883.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100118603; called by muse, mutect2, varscan2
- INTU | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV99611457; called by muse, mutect2, varscan2
- IQSEC3 | c.2331C>A p.D777E (on ENST00000538872 / NM_001170738.2; = p.D474E on NM_015232.1) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1347195748, COSV100406881; called by muse, mutect2, varscan2
- IRX2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs373076159; called by muse, mutect2, varscan2
- ITGAE | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99560457; called by muse, mutect2, varscan2
- ITSN2 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100742781; called by muse, mutect2, varscan2
- JADE3 | c.1672A>T p.T558S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); catalogued as COSV99509588; called by muse, mutect2, varscan2
- KCNC2 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100128297; called by muse, mutect2, varscan2
- KCNG3 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100044779; called by muse, mutect2, varscan2
- KCNJ14 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100655728, COSV60739009; called by muse, mutect2, varscan2
- KCNQ5 | c.1697G>A p.S566N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.456); catalogued as rs1300047060, COSV100571397; called by muse, mutect2, varscan2
- KCNS2 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419741727, COSV99750695; called by muse, mutect2, varscan2
- KCNT2 | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99651809; called by muse, mutect2, varscan2
- KIAA1958 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV100515884; called by muse, mutect2
- KIF13A | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99434221; called by muse, mutect2, varscan2
- KIF1A | c.2659G>T p.V887F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1355031628, COSV100239960, COSV100242133; called by muse, mutect2, varscan2
- KIF26B | c.3814G>T p.G1272W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1390707408, COSV100831694; called by muse, mutect2, varscan2
- KIR2DL1 | c.934C>A p.Q312K | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV99383639; called by muse, mutect2, varscan2
- KLC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs1240569511, COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2, varscan2
- KLHL4 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100909198; called by muse, mutect2, varscan2
- KLHL4 | c.1955C>G p.T652S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.1); catalogued as COSV100909199; called by muse, mutect2, varscan2
- KLHL6 | c.1690G>A p.G564S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384205; called by muse, mutect2, varscan2
- KMT2A | c.8152G>T p.D2718Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100628104; called by muse, mutect2, varscan2
- KRT17 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1355547921, COSV60860804, COSV60861067; called by muse, mutect2, varscan2
- KRTAP21-2 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as COSV100441102; called by muse, mutect2, varscan2
- KYNU | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99932831; called by muse, mutect2, varscan2
- LAMA1 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1166572404, COSV101055221; called by muse, mutect2, varscan2
- LAMA5 | c.3601G>T p.E1201* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99438320; called by muse, mutect2
- LAS1L | c.1838C>G p.T613R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.157); catalogued as COSV100408480, COSV56707847; called by muse, mutect2, varscan2
- LGI2 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | catalogued as COSV101180775, COSV66123033; called by muse, mutect2, varscan2
- LHFPL1 | c.410T>C p.L137S | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs113020239, COSV100779967; called by muse, mutect2, varscan2
- LILRA4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99392924; called by muse, mutect2, varscan2
- LIPF | c.502T>A p.Y168N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99490190; called by muse, mutect2, varscan2
- LY6K | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1554640424, COSV99456138; called by muse, mutect2, varscan2
- MACF1 | c.7305G>T p.L2435F | Missense Mutation (SNP) | VAF 36/61 reads (59%) | catalogued as COSV99241691; called by muse, mutect2, varscan2
- MAGEB18 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV57464903; called by muse, mutect2, varscan2
- MAP3K21 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100786235; called by muse, mutect2, varscan2
- MAT1A | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV100944453, COSV64747553; called by muse, mutect2, varscan2
- MATN2 | c.1268G>C p.S423T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV99645781; called by muse, mutect2, varscan2
- MDM1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV100291641; called by muse, mutect2, varscan2
- MIA3 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100738138; called by muse, mutect2, varscan2
- MITF | c.731T>C p.M244T (on ENST00000448226 / NM_006722.3; = p.M138T on NM_000248.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV100096522; called by muse, varscan2
- MLLT1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53131897, COSV99397885; called by muse, mutect2
- MMGT1 | c.362T>G p.L121W | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV100018409; called by muse, mutect2, varscan2
- MMP12 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1256449283, COSV58259651; called by muse, varscan2
- MMP27 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs1240039546, COSV99498260; called by muse, mutect2, varscan2
- MMRN1 | c.2288A>T p.H763L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV99306563; called by muse, mutect2, varscan2
- MNDA | c.73A>T p.I25F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100933253; called by muse, mutect2, varscan2
- MPEG1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs551823490, COSV57090064; called by muse, mutect2
- MPO | c.969C>A p.N323K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1197536833, COSV99832319; called by muse, mutect2, varscan2
- MRE11 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119464; called by muse, mutect2, varscan2
- MRGPRX4 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100049646; called by muse, mutect2, varscan2
- MROH2B | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV101270533; called by muse, mutect2, varscan2
- MUC16 | c.28828G>T p.G9610C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as rs772993255, COSV101198373; called by muse, mutect2, varscan2
- MUC16 | c.26299A>T p.T8767S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1160949929, COSV101198374; called by muse, mutect2, varscan2
- MUC16 | c.13813G>T p.E4605* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101198376; called by muse, mutect2
- MUC5B | c.12992T>A p.L4331H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.429); catalogued as COSV101500059; called by muse, mutect2, varscan2
- MUSK | c.641T>A p.I214N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99503730; called by muse, mutect2
- MUTYH | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100587928; called by muse, mutect2, varscan2
- MYO19 | c.1999G>T p.E667* (on ENST00000614623 / NM_001163735.1; = p.E467* on NM_025109.5) | Nonsense Mutation (SNP) | VAF 57/128 reads (45%) | catalogued as rs1567736037; called by muse, mutect2, varscan2
- MYO6 | c.3311A>G p.D1104G (on ENST00000369981; = p.D1094G on NM_004999.4) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64118997; called by muse, mutect2, varscan2
- NABP2 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99907359; called by muse, mutect2, varscan2
- NALCN | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99213269; called by muse, mutect2
- NAV2 | c.3173G>T p.G1058V (on ENST00000396087 / NM_001244963.2; = p.G1035V on NM_145117.5) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771443047, COSV100216267, COSV100216351; called by muse, mutect2, varscan2
- NAV3 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.422); catalogued as COSV99887434; called by muse, mutect2
- NBEA | c.7291G>T p.V2431L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs780703650, COSV100077216; called by muse, mutect2, varscan2
- NCAPD2 | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100216900; called by muse, mutect2
- NEK10 | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100411453; called by muse, mutect2, varscan2
- NID1 | c.2654C>A p.A885E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749480537, COSV51627037, COSV99937052; called by muse, mutect2
- NKAPL | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1171244961, COSV100642462; called by muse, mutect2, varscan2
- NLRP3 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.131); catalogued as COSV100275338, COSV60232039; called by muse, mutect2, varscan2
- NLRP5 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.084); catalogued as COSV101173409; called by muse, mutect2, varscan2
- NME8 | c.1516T>C p.Y506H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs977691422, COSV99552868; called by muse, mutect2, varscan2
- NOC3L | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100993259; called by muse, mutect2, varscan2
- NOL4 | c.1022A>G p.K341R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.445); catalogued as COSV99305260; called by muse, mutect2, varscan2
- NOTCH3 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV54635036, COSV99656086; called by muse, mutect2, varscan2
- NRCAM | c.226C>A p.P76T (on ENST00000379028 / NM_001371124.1; = p.P70T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100694287; called by muse, mutect2
- NRXN1 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV101276744; called by muse, mutect2, varscan2
- NSF | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as COSV99833693; called by muse, mutect2, varscan2
- NTRK3 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.216); catalogued as rs1434105549, COSV100445688; called by muse, mutect2, varscan2
- NUP205 | c.4344G>T p.M1448I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs1436670342, COSV99606540, COSV99607637; called by muse, varscan2
- NUP35 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs752232161, COSV99717728; called by muse, mutect2, varscan2
- OCA2 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as COSV100667014; called by muse, mutect2, varscan2
- OCRL | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100843348; called by muse, mutect2, varscan2
- OLFM1 | c.1399G>A p.G467S (on ENST00000371793 / NM_001282611.2; = p.G449S on NM_014279.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs774962345, COSV53278064; called by muse, mutect2, varscan2
- OLFM3 | c.155G>T p.W52L (on ENST00000338858 / NM_001288821.1; = p.W32L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1286514160, COSV100128958; called by muse, mutect2, varscan2
- OPHN1 | c.1797G>T p.R599S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100830237; called by muse, mutect2, varscan2
- OR10P1 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100548115, COSV59006704; called by muse, mutect2, varscan2
- OR10Q1 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV57471964, COSV57472128; called by muse, mutect2, varscan2
- OR10R2 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1349549732, COSV63769198; called by muse, mutect2, varscan2
- OR10S1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV101602446, COSV73342864; called by muse, mutect2, varscan2
- OR11L1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.216); catalogued as COSV100869391; called by mutect2, varscan2
- OR2M3 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.08); catalogued as COSV101513398; called by muse, mutect2, varscan2
- OR2T6 | c.795C>G p.Y265* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100861488; called by muse, mutect2, varscan2
- OR4C11 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100155221; called by muse, mutect2, varscan2
- OR4P4 | c.851T>A p.I284K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100111576; called by muse, mutect2, varscan2
- OR4Q3 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.106); catalogued as COSV100056748; called by muse, mutect2, varscan2
- OR51A4 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100985199; called by muse, mutect2, varscan2
- OR52A1 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100200428; called by muse, mutect2, varscan2
- OR56A4 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100417471; called by muse, mutect2, varscan2
- OR5M11 | c.831C>A p.Y277* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV101602022; called by muse, mutect2
- OR5T1 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.949); catalogued as COSV100478754, COSV57304723; called by muse, mutect2, varscan2
- OR5W2 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1267498155, COSV100747553, COSV100747629; called by muse, varscan2
- OR9A2 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV100628169; called by muse, mutect2, varscan2
- OSBPL8 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53890106, COSV99674584; called by muse, mutect2, varscan2
- OTOP1 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as COSV99587402; called by muse, mutect2, varscan2
- OTOP1 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV99587403; called by muse, mutect2, varscan2
- PALD1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.047); catalogued as COSV99698011; called by muse, mutect2, varscan2
- PAPPA | c.2234-2A>G p.X745_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as rs1445096639, COSV100073018; called by muse, mutect2, varscan2
- PAPPA | c.3260G>T p.R1087L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs200046193, COSV100073020; called by muse, mutect2, varscan2
- PAPPA2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV100866459, COSV62785917; called by muse, mutect2, varscan2
- PAPPA2 | c.962G>A p.W321* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs1431085725, COSV62785924; called by muse, mutect2, varscan2
- PAX6 | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99570120; called by muse, mutect2, varscan2
- PBX2 | c.929A>T p.Q310L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100903974; called by muse, mutect2, varscan2
- PCDH11X | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100008851; called by mutect2, varscan2
- PCDHA12 | c.1251C>G p.S417R | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.118); catalogued as COSV100248026, COSV56549338; called by muse, mutect2, varscan2
- PCDHA5 | c.1505C>G p.P502R | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV100972136, COSV100972359; called by muse, mutect2, varscan2
- PCDHB2 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99164248; called by muse, mutect2, varscan2
- PCDHGB3 | c.1629C>A p.S543R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV99532024; called by muse, mutect2, varscan2
- PCDHGB3 | c.1972G>T p.V658F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53965210, COSV99532029; called by muse, mutect2, varscan2
- PCMTD2 | c.102A>T p.R34S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55058948; called by muse, mutect2, varscan2
- PDE2A | c.2528G>T p.R843M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV100557678; called by muse, mutect2, varscan2
- PDE4B | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326879018, COSV100302426; called by muse, mutect2, varscan2
- PDIA3 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100082484; called by muse, mutect2, varscan2
- PDP1 | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.068); catalogued as COSV99891969; called by muse, mutect2
- PDZRN4 | c.2140A>T p.I714L (on ENST00000402685 / NM_001164595.2; = p.I456L on NM_013377.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100113755, COSV54215902; called by muse, mutect2, varscan2
- PEG3 | c.1529G>T p.C510F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753853974, COSV55628043; called by muse, mutect2, varscan2
- PHF3 | c.2528G>T p.C843F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs769729722, COSV100012937; called by muse, mutect2, varscan2
- PI4KB | c.665A>G p.D222G (on ENST00000368873 / NM_001369623.1; = p.D234G on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1297360702, COSV99649341; called by muse, mutect2, varscan2
- PIK3AP1 | c.1951A>G p.K651E | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100225542; called by muse, mutect2, varscan2
- PIWIL4 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752333176, COSV100133075; called by muse, mutect2, varscan2
- PJA1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100824663; called by muse, mutect2, varscan2
- PKHD1 | c.1658G>C p.W553S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100581418; called by muse, mutect2, varscan2
- PLEKHM3 | c.1131G>T p.W377C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101216306; called by muse, mutect2, varscan2
- PLPPR4 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs1320410416, COSV64565161; called by muse, mutect2, varscan2
- PLPPR4 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100926709, COSV64567728; called by muse, mutect2, varscan2
- PLVAP | c.726G>T p.R242S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99391501; called by muse, mutect2, varscan2
- PLXNB3 | c.3323G>A p.C1108Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100737163; called by muse, mutect2, varscan2
- PLXNC1 | c.3653G>T p.R1218L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.905); catalogued as COSV99312530, COSV99313932; called by muse, mutect2, varscan2
- PLXND1 | c.5566C>T p.H1856Y | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as rs1245924801, COSV100139123; called by muse, mutect2, varscan2
- PNLIP | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769861164, COSV100981647; called by muse, mutect2, varscan2
- POSTN | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321269024, COSV101123256, COSV65711782; called by muse, mutect2, varscan2
- POU6F2 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1463388281, COSV101302499, COSV68879426; called by muse, mutect2, varscan2
- PPP1R16B | c.369T>A p.H123Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.588); catalogued as COSV100239048; called by muse, mutect2, varscan2
- PPP1R16B | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV100239049; called by muse, mutect2, varscan2
- PPP2R2C | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100160251, COSV59441969; called by muse, mutect2
- PPT2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.227); catalogued as COSV99278239; called by muse, mutect2, varscan2
- PRAM1 | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV99725273; called by muse, mutect2
- PRB2 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.51); catalogued as COSV101231378; called by muse, varscan2
- PRORP | c.1276-1G>T p.X426_splice | Splice Site (SNP) | VAF 44/91 reads (48%) | catalogued as rs1289251914, COSV99154957; called by muse, mutect2, varscan2
- PRPF8 | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100517188; called by muse, mutect2, varscan2
- PSG4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as COSV99736382; called by muse, mutect2, varscan2
- PTCH1 | c.4073G>T p.G1358V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.086); catalogued as COSV100107809, COSV59476056; called by muse, mutect2, varscan2
- PTGFR | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66116001; called by muse, mutect2, varscan2
- PTPN22 | c.1351C>G p.P451A (on ENST00000359785 / NM_001193431.2; = p.P396A on NM_012411.5) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs774164587, COSV100703422; called by muse, mutect2, varscan2
- PTPN23 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387784098, COSV99650239; called by mutect2, varscan2
- PTPRZ1 | c.4301G>T p.S1434I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV101099653; called by muse, mutect2, varscan2
- PXDNL | c.3511C>A p.L1171I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV62502457; called by muse, mutect2
- PYGM | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs1299991104, COSV99376797; called by muse, mutect2, varscan2
- PYROXD1 | c.918G>C p.K306N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV99556307; called by muse, mutect2, varscan2
- PZP | c.4291C>G p.Q1431E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99736491; called by muse, mutect2, varscan2
- R3HCC1L | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1462449187, COSV100107119, COSV54402823; called by muse, mutect2, varscan2
- RAB3GAP2 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs1305324295, COSV99424472; called by muse, mutect2, varscan2
- RAB6B | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV99557815; called by muse, mutect2, varscan2
- RALGPS2 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs553341800, COSV100243586; called by muse, mutect2, varscan2
- RAPH1 | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100051137, COSV57352490; called by mutect2, varscan2
- RASGRP4 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99498417; called by muse, mutect2
- RB1 | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as CM040259, COSV57335540; called by muse, mutect2, varscan2
- RBM12 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100467066; called by muse, mutect2, varscan2
- REG3G | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); catalogued as COSV99709251; called by muse, mutect2, varscan2
- RET | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100392577, COSV60709761; called by muse, mutect2, varscan2
- RFPL1 | c.775T>A p.F259I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100585649; called by muse, mutect2, varscan2
- RNF169 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs747254976, COSV100213234; called by muse, mutect2, varscan2
- RNF213 | c.12644G>A p.R4215Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs761110619, COSV100299820; called by muse, mutect2, varscan2
- RP1L1 | c.3282G>T p.Q1094H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101222985; called by muse, mutect2
- RREB1 | c.3655A>T p.S1219C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100619169; called by muse, mutect2, varscan2
- RRM2B | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs1407022753, COSV99309906; called by muse, mutect2, varscan2
- RYR2 | c.9617_9618insT p.N3207Kfs*49 | Frame Shift Ins (INS) | VAF 63/142 reads (44%) | catalogued as COSV100768325; called by mutect2, pindel, varscan2
- RYR3 | c.2275G>T p.G759W | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212074; called by muse, mutect2, varscan2
- SACS | c.10011C>G p.I3337M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV101207213; called by muse, mutect2
- SAGE1 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.423); catalogued as COSV100186750; called by muse, mutect2, varscan2
- SAMD9 | c.4396G>T p.G1466W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV101180134; called by muse, mutect2, varscan2
- SAMD9 | c.4395G>T p.K1465N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101180135, COSV66072975; called by muse, mutect2, varscan2
- SCARA5 | c.1480A>T p.R494* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100720248; called by muse, mutect2, varscan2
- SCGB1C1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as rs779699387, COSV100285182, COSV57294755; called by muse, mutect2, varscan2
- SCGB2A2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99929280; called by muse, mutect2, varscan2
- SCYL1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs974182929, COSV99533814; called by muse, mutect2, varscan2
- SEMA3C | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV54854353, COSV99542458; called by muse, mutect2, varscan2
- SEMA3E | c.2144A>T p.Q715L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100317498; called by muse, mutect2, varscan2
- SEPTIN14 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241695658, COSV101193218, COSV66426452; called by muse, mutect2, varscan2
- SETX | c.3350C>T p.T1117I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1564541749, COSV99808917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEZ6L | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV99961463; called by muse, mutect2, varscan2
- SHKBP1 | c.288T>A p.H96Q | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52539735, COSV99398937; called by muse, mutect2, varscan2
- SIGLEC10 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100218528; called by muse, mutect2, varscan2
- SLC16A7 | c.1353G>C p.L451F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99676208; called by muse, mutect2
- SLC22A11 | c.678G>T p.R226S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as COSV100102124, COSV57251909; called by muse, mutect2, varscan2
- SLC22A25 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs1277606509, COSV100123442; called by muse, mutect2, varscan2
- SLC24A2 | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645891; called by muse, mutect2, varscan2
- SLC2A10 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.082); catalogued as rs201268555, CM1411099, COSV63714674, COSV63716448; called by muse, mutect2, varscan2
- SLC30A6 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99249365; called by muse, mutect2, varscan2
- SLC32A1 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461856; called by muse, mutect2, varscan2
- SLC37A1 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721578, COSV100721842; called by muse, mutect2, varscan2
- SLC3A1 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99576865; called by muse, mutect2, varscan2
- SLC45A3 | c.935A>T p.E312V | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100901083; called by muse, mutect2, varscan2
- SLC45A4 | c.1322G>T p.R441L (on ENST00000517878 / NM_001286646.2; = p.R390L on NM_001080431.2) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99196639; called by muse, mutect2, varscan2
- SLC4A8 | c.2326G>T p.G776C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176509; called by muse, mutect2, varscan2
- SLC8A3 | c.1589G>A p.G530D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775949; called by muse, mutect2, varscan2
- SLC8A3 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100775950; called by muse, mutect2, varscan2
- SLC9A4 | c.1199-1G>T p.X400_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV99762749; called by muse, mutect2, varscan2
- SLITRK1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs866867094, COSV100999804; called by muse, mutect2, varscan2
- SLITRK2 | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV100157382; called by muse, mutect2, varscan2
- SLITRK3 | c.2642G>T p.G881V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.182); catalogued as COSV99578596; called by muse, mutect2, varscan2
- SLITRK3 | c.2252G>T p.C751F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99578600; called by muse, mutect2
- SMARCA1 | c.2762G>C p.R921P | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100946382; called by muse, mutect2, varscan2
- SMC6 | c.2434A>G p.K812E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV100704818; called by muse, mutect2, varscan2
- SMCHD1 | c.3106G>T p.V1036F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV55256333; called by muse, mutect2, varscan2
- SMCP | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.599); catalogued as COSV64218031; called by muse, mutect2, varscan2
- SMYD1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV101352403, COSV70226000, COSV70226034; called by muse, mutect2, varscan2
- SMYD3 | c.1077G>A p.R359= (on ENST00000490107 / NM_001375962.1; = p.R300= on NM_022743.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100830664; called by muse, mutect2, varscan2
- SNTG1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99381691; called by muse, mutect2, varscan2
- SORL1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99493005; called by muse, mutect2, varscan2
- SORL1 | c.6566G>T p.G2189V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778654866, COSV99492615; called by muse, mutect2, varscan2
- SP140 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1238961052, COSV100613431; called by muse, mutect2, varscan2
- SPAG7 | c.621G>T p.M207I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV52779684, COSV99236217; called by muse, mutect2, varscan2
- SPATA2 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as COSV99192744; called by muse, mutect2, varscan2
- SPECC1L | c.2980A>G p.I994V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV100061851, COSV58662203; called by muse, mutect2, varscan2
- SPPL2A | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55941198; called by muse, varscan2
- SPZ1 | c.301A>C p.N101H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.465); catalogued as rs1254364658, COSV99698076; called by muse, mutect2, varscan2
- SS18 | c.1096G>A p.G366S (on ENST00000415083 / NM_001007559.3; = p.G335S on NM_005637.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs1454888403, COSV99293927; called by muse, mutect2, varscan2
- SS18L1 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as rs768858948, COSV100064538; called by muse, mutect2, varscan2
- SSU72P8 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 33/58 reads (57%) | catalogued as rs1393231386; called by muse, mutect2, varscan2
- STIL | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54547003, COSV99680619; called by muse, mutect2, varscan2
- STN1 | c.582-2A>T p.X194_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99830119; called by muse, mutect2, varscan2
- STX8 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110936; called by muse, mutect2, varscan2
- SV2B | c.60C>A p.Y20* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100370426; called by muse, varscan2
- SYCP2 | c.3767C>G p.S1256C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV100698004, COSV62772177; called by muse, mutect2, varscan2
- SYNE2 | c.18694C>T p.R6232W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772056587, COSV100646830; called by muse, mutect2, varscan2
- SYT13 | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV99194652, COSV99194889; called by muse, mutect2
- TAB3 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99915847; called by muse, mutect2, varscan2
- TACC2 | c.2260G>T p.G754C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100551669; called by muse, mutect2, varscan2
- TAF1 | c.3599T>A p.M1200K (on ENST00000373790 / NM_138923.4; = p.M1221K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV99334660; called by muse, mutect2, varscan2
- TAF1L | c.5227G>A p.D1743N | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.388); catalogued as COSV54270380; called by muse, mutect2, varscan2
- TAF1L | c.4972C>A p.P1658T | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as COSV99644189; called by muse, mutect2, varscan2
- TAGAP | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100487290; called by muse, mutect2, varscan2
- TASOR2 | c.2978G>A p.S993N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100050024; called by muse, mutect2, varscan2
- TBX5 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as COSV100090635; called by muse, mutect2, varscan2
- TENT5D | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV100382572; called by muse, mutect2, varscan2
- TEX11 | c.400G>C p.D134H (on ENST00000344304; = p.D119H on NM_031276.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100721367; called by muse, mutect2, varscan2
- TEX15 | c.4820C>A p.S1607* (on ENST00000256246; = p.S1990* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99820790; called by muse, mutect2, varscan2
- TF | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748119838, COSV53917789; called by muse, mutect2, varscan2
- TGFBR3 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53030329; called by muse, mutect2, varscan2
- TGFBR3 | c.674G>C p.S225T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.11); catalogued as COSV99282472; called by muse, mutect2, varscan2
- TIMELESS | c.3304G>T p.E1102* | Nonsense Mutation (SNP) | VAF 35/141 reads (25%) | catalogued as COSV57515784, COSV99973701; called by muse, mutect2, varscan2
- TLK2 | c.1936C>G p.P646A (on ENST00000326270 / NM_001284333.2; = p.P624A on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408761; called by muse, mutect2
- TMEM132B | c.1004G>T p.W335L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164106404, COSV100168733, COSV100169131; called by muse, mutect2, varscan2
- TMEM171 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99824867; called by muse, mutect2
- TMEM187 | c.634C>G p.H212D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100890146; called by muse, mutect2, varscan2
- TMEM37 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99191519; called by muse, mutect2, varscan2
- TMEM63A | c.1294G>T p.G432W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1160884835, COSV100834276; called by muse, mutect2, varscan2
- TMEM63B | c.1575G>T p.M525I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52482409; called by muse, mutect2, varscan2
- TNNT2 | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99372081; called by muse, mutect2, varscan2
- TNS2 | c.1177G>T p.G393* (on ENST00000314250 / NM_170754.4; = p.G403* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100047541, COSV58582221; called by muse, mutect2, varscan2
- TPTE | c.939-1G>T p.X313_splice (on ENST00000618007 / NM_199261.4; = p.X295_splice on NM_199259.4) | Splice Site (SNP) | VAF 19/175 reads (11%) | catalogued as rs1293876531; called by muse, mutect2, varscan2
- TRAF3 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as COSV100693475; called by muse, mutect2, varscan2
- TRAV12-3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs370888273; called by muse, mutect2, varscan2
- TREX2 | c.318C>G p.C106W (on ENST00000334497; = p.C63W on NM_080701.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100444005; called by muse, mutect2, varscan2
- TRMT10A | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1256755430, COSV99910846; called by muse, mutect2, varscan2
- TRMT10A | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs1444127634, COSV99910848; called by muse, mutect2, varscan2
- TRPM1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV99855458; called by muse, mutect2, varscan2
- TSPYL6 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100336327; called by muse, mutect2, varscan2
- TSSK1B | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1211740915, COSV101180967; called by muse, mutect2, varscan2
- TTN | c.101831A>C p.E33944A (on ENST00000591111; = p.E26520A on NM_003319.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | PolyPhen benign (0.037); catalogued as COSV100596850; called by muse, mutect2, varscan2
- TXLNB | c.1257G>C p.M419I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100624795, COSV100624859; called by muse, mutect2, varscan2
- TXNDC12 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.33); catalogued as rs1380181050, COSV100860143; called by muse, mutect2
- UBR5 | c.5183G>T p.S1728I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99639584; called by muse, mutect2, varscan2
- UBR5 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as rs1470174028, COSV99639588; called by muse, mutect2, varscan2
- UGT2A3 | c.745G>C p.G249R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99279639; called by muse, mutect2, varscan2
- UGT2B28 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100158588, COSV100158976; called by muse, mutect2, varscan2
- UGT3A1 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV99954368; called by muse, mutect2, varscan2
- UNC13C | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as COSV52895279, COSV99512424; called by muse, mutect2, varscan2
- UNC79 | c.6961G>T p.V2321L (on ENST00000393151 / NM_001346218.2; = p.V2144L on NM_020818.5) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99826090; called by muse, mutect2, varscan2
- UPF3B | c.1008-2A>G p.X336_splice (on ENST00000276201 / NM_080632.3; = p.X323_splice on NM_023010.3) | Splice Site (SNP) | VAF 13/102 reads (13%) | catalogued as COSV99351993; called by muse, mutect2, varscan2
- URM1 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100864858; called by muse, mutect2, varscan2
- USH1G | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs372580540, COSV58881006; called by mutect2, varscan2
- USP15 | c.1726A>T p.R576* (on ENST00000280377 / NM_001351159.2; = p.R547* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99738666; called by muse, mutect2, varscan2
- UTP20 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV99880885; called by muse, mutect2, varscan2
- VAC14 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55756040; called by muse, mutect2, varscan2
- VANGL2 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100925537; called by muse, mutect2, varscan2
- VGLL2 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100409847; called by muse, mutect2, varscan2
- VPS8 | c.580A>G p.S194G (on ENST00000625842 / NM_001349294.1; = p.S192G on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99800906; called by muse, mutect2
- WASF2 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV101420725; called by muse, mutect2, varscan2
- WDR88 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100866424; called by muse, mutect2, varscan2
- WDR91 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100615578; called by muse, mutect2, varscan2
- WRAP73 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV99573142; called by muse, mutect2
- WWC3 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101081106; called by muse, mutect2, varscan2
- XIRP2 | c.8273C>A p.S2758Y (on ENST00000628543; = p.S2933Y on NM_152381.6) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99739049; called by muse, mutect2, varscan2
- YES1 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV100099293; called by muse, mutect2, varscan2
- ZBTB2 | c.938G>C p.G313A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.264); catalogued as COSV100287507; called by muse, mutect2, varscan2
- ZBTB4 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100043453; called by muse, mutect2, varscan2
- ZDBF2 | c.647T>A p.V216D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100984413; called by muse, mutect2, varscan2
- ZEB1 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100313755; called by muse, mutect2
- ZFHX4 | c.2260G>T p.G754* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV50482685, COSV99257354; called by muse, mutect2
- ZFHX4 | c.8359C>A p.P2787T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.12); catalogued as COSV99257358; called by muse, mutect2, varscan2
- ZFYVE16 | c.3130C>G p.H1044D | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100566230, COSV62015489, COSV62017870; called by muse, mutect2, varscan2
- ZIM3 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.441); catalogued as COSV99517740; called by muse, mutect2, varscan2
- ZNF107 | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100788236, COSV61331187; called by muse, mutect2, varscan2
- ZNF134 | c.688A>T p.R230W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101270703; called by muse, mutect2, varscan2
- ZNF160 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 43/123 reads (35%) | catalogued as COSV100762246; called by muse, mutect2, varscan2
- ZNF211 | c.1682G>C p.G561A (on ENST00000347302 / NM_198855.4; = p.G574A on NM_006385.5) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV53746212, COSV99560086; called by muse, mutect2, varscan2
- ZNF283 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100190374; called by muse, mutect2, varscan2
- ZNF382 | c.1124C>A p.T375K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53086401, COSV99497506; called by muse, mutect2, varscan2
- ZNF462 | c.4688T>C p.V1563A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99470898; called by muse, mutect2, varscan2
- ZNF492 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV101513947; called by muse, mutect2, varscan2
- ZNF493 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.687); catalogued as COSV100828577, COSV62751053; called by muse, mutect2, varscan2
- ZNF507 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 55/141 reads (39%) | catalogued as COSV100321583; called by muse, mutect2, varscan2
- ZNF536 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252470871, COSV100834759; called by muse, mutect2, varscan2
- ZNF570 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356037, COSV57579418; called by muse, mutect2, varscan2
- ZNF572 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100073825, COSV60002208; called by muse, mutect2, varscan2
- ZNF695 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100377274, COSV60587183; called by muse, mutect2, varscan2
- ZNF711 | c.1620C>A p.F540L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV52156025, COSV99340701; called by muse, mutect2, varscan2
- ZNF74 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100677431; called by muse, mutect2
- ZNF761 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV100483267; called by muse, mutect2, varscan2
- ZNF829 | c.39-1G>T p.X13_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100451182; called by muse, mutect2, varscan2
- ZNF831 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1288071352, COSV100925803; called by muse, mutect2, varscan2
- ABCA13 | c.13372G>A p.V4458M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF6 | c.945dup p.V316Sfs*13 | Frame Shift Ins (INS) | VAF 42/185 reads (23%) | called by pindel, varscan2
- DDX52 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DKK4 | c.103del p.A35Pfs*52 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.2266del p.E756Sfs*55 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- IGHV3-53 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGKV1-27 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IGKV1D-16 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL9R | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- OR6S1 | c.34del p.T12Qfs*28 | Frame Shift Del (DEL) | VAF 60/138 reads (43%) | called by mutect2, pindel, varscan2
- PLG | c.1238dup p.E414Rfs*20 | Frame Shift Ins (INS) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- PODXL | c.1088del p.G363Efs*14 (on ENST00000378555 / NM_001018111.3; = p.G331Efs*14 on NM_005397.4) | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); called by muse, mutect2
- RNF148 | c.442del p.E148Kfs*3 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | called by pindel, varscan2
- RPL18 | c.389_421+2del p.X130_splice | Splice Site (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- SLC1A6 | c.1231dup p.I411Nfs*32 | Frame Shift Ins (INS) | VAF 17/40 reads (43%) | called by mutect2, varscan2
- SVEP1 | c.4625del p.G1542Vfs*10 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SYNRG | c.2198A>C p.K733T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TAF15 | c.1676G>T p.G559V (on ENST00000605844 / NM_139215.3; = p.G556V on NM_003487.4) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- WASHC2A | c.2561A>T p.D854V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZC4H2 | c.97del p.A33Lfs*13 | Frame Shift Del (DEL) | VAF 32/70 reads (46%) | called by mutect2, pindel, varscan2
- ABHD1 | c.72C>T p.A24= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99565015; called by muse, mutect2, varscan2
- ACSS3 | c.1299G>T p.L433= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54093413, COSV99698371; called by muse, mutect2, varscan2
- ACTL9 | c.1116C>A p.A372= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100185138; called by muse, mutect2, varscan2
- ACTN3 | c.2079C>A p.I693= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100074129; called by muse, mutect2
- ADAMTSL1 | c.2538G>T p.L846= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV101001380; called by muse, mutect2, varscan2
- AMT | c.12T>A p.A4= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV99864411; called by muse, mutect2, varscan2
- ANO2 | c.1875G>A p.L625= (on ENST00000356134 / NM_001278597.3; = p.L629= on NM_001278596.3) | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- APOA1 | c.753C>T p.V251= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99369144; called by muse, mutect2, varscan2
- APOB | c.10362C>A p.V3454= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV51949173, COSV99263900; called by muse, varscan2
- ARMCX5-GPRASP2 | c.210G>C p.T70= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100771824; called by muse, mutect2, varscan2
- ASIC4 | c.370C>A p.R124= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1246195746, COSV100761577; called by muse, mutect2
- ATR | c.3624G>T p.L1208= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100637727; called by muse, mutect2, varscan2
- B4GALT3 | c.1095C>T p.F365= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs367859921, COSV60526943; called by muse, mutect2, varscan2
- BAG4 | c.873A>T p.P291= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99781735; called by muse, mutect2, varscan2
- BCORL1 | c.3249G>T p.R1083= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV99498631; called by muse, mutect2, varscan2
- BRI3 | c.369C>G p.T123= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV50054993, COSV50056662; called by muse, mutect2, varscan2
- C16orf78 | c.318C>A p.L106= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV54556410; called by muse, mutect2, varscan2
- C2CD2 | c.1989G>T p.R663= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100298016, COSV100298352; called by muse, mutect2, varscan2
- C9orf64 | c.648G>T p.T216= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100123496, COSV59032703; called by muse, mutect2, varscan2
- CACNA1F | c.4257C>A p.A1419= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100544412; called by muse, mutect2, varscan2
- CACNG2 | c.819C>A p.L273= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV100268567; called by muse, mutect2, varscan2
- CCDC89 | c.657C>A p.A219= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs779053768, COSV100320809; called by muse, mutect2, varscan2
- CD79B | c.258C>A p.P86= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99137609; called by muse, mutect2, varscan2
- CEP78 | c.831A>T p.L277= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99450021; called by muse, mutect2, varscan2
- CFAP74 | c.318G>T p.R106= | Silent (SNP) | VAF 36/52 reads (69%) | called by muse, mutect2, varscan2
- CLEC1B | c.144G>A p.L48= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100045967; called by muse, mutect2, varscan2
- CLRN2 | c.495G>T p.T165= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV101492683, COSV71825279; called by muse, mutect2, varscan2
- CNGB1 | c.3066G>T p.L1022= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV99201624; called by muse, mutect2, varscan2
- COL22A1 | c.2856T>A p.G952= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100276607; called by muse, mutect2, varscan2
- COL3A1 | c.4146C>A p.A1382= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100482588; called by muse, mutect2, varscan2
- DBX2 | c.417T>A p.P139= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100224212; called by muse, mutect2, varscan2
- DDR1 | c.996G>T p.R332= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1248019115, COSV100241082; called by muse, mutect2, varscan2
- DLG2 | c.954C>G p.S318= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99712962; called by muse, mutect2, varscan2
- DLG5 | c.2844C>T p.P948= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1279376644, COSV100967281; called by muse, mutect2, varscan2
- DNAH1 | c.2877A>T p.V959= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV101324871; called by muse, mutect2, varscan2
- DOCK4 | c.4035G>T p.L1345= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV101445581; called by muse, mutect2, varscan2
- DSCAM | c.2460C>T p.R820= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs752336765, COSV101259235; called by muse, mutect2, varscan2
- ERG | c.33T>C p.H11= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV101296365; called by muse, mutect2, varscan2
- EVX2 | c.408T>A p.L136= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV57963960; called by muse, mutect2
- FAM135B | c.1812C>A p.A604= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV52725632, COSV99423864; called by muse, mutect2, varscan2
- FAM47C | c.27G>A p.R9= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100792328, COSV100792874, COSV63727200; called by muse, mutect2, varscan2
- FAM90A1 | c.810C>T p.C270= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100274207; called by muse, mutect2, varscan2
- FBN3 | c.3243C>T p.L1081= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99560020; called by muse, mutect2
- FBXO47 | c.519A>T p.A173= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100960566; called by muse, mutect2, varscan2
- FCRL1 | c.798G>T p.L266= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100839729; called by muse, mutect2, varscan2
- FDX1 | c.501G>T p.V167= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99501761; called by muse, varscan2
- FEM1B | c.1728G>T p.P576= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100183554; called by muse, mutect2, varscan2
- FLNA | c.7407C>A p.P2469= (on ENST00000369850 / NM_001110556.2; = p.P2461= on NM_001456.3) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100774329; called by muse, mutect2, varscan2
- FLNC | c.4851C>A p.G1617= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV100367676; called by muse, mutect2, varscan2
- FOXB1 | c.141C>T p.F47= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs1238001291, COSV101249688; called by muse, mutect2, varscan2
- FOXO3 | c.1041C>G p.L347= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100669589; called by muse, mutect2
- FSHR | c.1092C>A p.I364= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1269125579, COSV100436636, COSV58631313; called by muse, mutect2, varscan2
- FSHR | c.471C>A p.I157= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100436637, COSV58624028; called by muse, mutect2, varscan2
- GID4 | c.747C>T p.I249= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1462307329, COSV99254067; called by muse, mutect2, varscan2
- GRIN2B | c.2376G>T p.L792= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV101662932; called by muse, mutect2
- GUK1 | c.330C>A p.I110= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100451623; called by muse, mutect2, varscan2
- H6PD | c.24G>T p.A8= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101072426; called by muse, mutect2, varscan2
- HAS2 | c.516G>T p.T172= | Silent (SNP) | VAF 41/222 reads (18%) | catalogued as COSV100391485, COSV58262635; called by muse, mutect2, varscan2
- HIC2 | c.789C>T p.P263= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV101335542; called by muse, mutect2, varscan2
- HOXA13 | c.1062G>A p.R354= | Silent (SNP) | VAF 85/352 reads (24%) | catalogued as COSV99763491; called by muse, mutect2, varscan2
- HSFX1 | c.111C>A p.T37= | Silent (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- IFIT1 | c.1392G>C p.L464= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100878672; called by muse, mutect2, varscan2
- IGKV3D-20 | c.90C>A p.T30= | Silent (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- IGSF1 | c.30C>A p.A10= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100811854; called by muse, mutect2, varscan2
- IL10RA | c.708C>G p.V236= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99922894; called by muse, varscan2
- IL12RB2 | c.705A>G p.Q235= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as COSV99254724; called by muse, mutect2, varscan2
- IRS1 | c.1167G>T p.P389= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100524088; called by muse, mutect2, varscan2
- IRS4 | c.3012T>C p.A1004= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV100929445, COSV64535968; called by muse, mutect2, varscan2
- KATNIP | c.3162G>T p.R1054= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs557548894, COSV99850018; called by muse, mutect2, varscan2
- KBTBD13 | c.1266G>T p.R422= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1183975712, COSV71351688; called by muse, mutect2, varscan2
- KCNH1 | c.129G>T p.V43= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV55099014, COSV99657567; called by muse, mutect2, varscan2
- KCNJ12 | c.468G>T p.P156= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs781962014, COSV100054120, COSV59168088, COSV59175448; called by muse, varscan2
- KCNJ3 | c.474C>A p.G158= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV54543635; called by muse, mutect2, varscan2
- KCNMB4 | c.174G>C p.S58= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1250502572, COSV99252919; called by muse, mutect2, varscan2
- KIAA0319 | c.2265C>A p.I755= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV65499564; called by muse, mutect2, varscan2
- KIF17 | c.1047G>T p.L349= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs752447121, COSV56118955; called by muse, mutect2, varscan2
- KIF4A | c.2601G>T p.L867= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100979405; called by muse, mutect2, varscan2
- KYNU | c.1353C>A p.T451= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV51587388, COSV99932832; called by muse, mutect2, varscan2
- LILRB4 | c.570G>T p.G190= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99553528; called by muse, mutect2, varscan2
- MARVELD2 | c.324C>T p.Y108= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100347408; called by muse, mutect2, varscan2
- MASP2 | c.897T>A p.P299= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV101280061; called by muse, mutect2, varscan2
- METAP1D | c.258A>T p.I86= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100249825; called by muse, mutect2, varscan2
- MGAT1 | c.1293G>C p.L431= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100286535; called by muse, mutect2, varscan2
- MMP12 | c.403C>A p.R135= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100404828, COSV58262019; called by muse, varscan2
- MOCS3 | c.195G>T p.R65= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV54868260; called by muse, mutect2, varscan2
- MORC4 | c.391C>A p.R131= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as COSV55247292, COSV99716858; called by muse, mutect2, varscan2
- MUC16 | c.43434C>A p.T14478= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV101109656; called by muse, mutect2, varscan2
- MUC16 | c.33045C>A p.T11015= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV101198372; called by muse, mutect2, varscan2
- MUC2 | c.1914C>T p.A638= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- MUC21 | c.990C>T p.A330= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs1412320256, COSV100888835; called by muse, mutect2, varscan2
- MYH11 | c.2328C>A p.A776= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV100257860; called by muse, mutect2, varscan2
- MYH11 | c.1710G>A p.K570= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1002156010, COSV100257863, COSV100258916; called by muse, mutect2, varscan2
- NAALAD2 | c.543G>A p.E181= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100428091; called by muse, mutect2, varscan2
- NEB | c.6192C>T p.Y2064= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99415781; called by muse, mutect2, varscan2
- NEK9 | c.1077C>A p.P359= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99463597; called by muse, mutect2, varscan2
- NIPSNAP1 | c.165G>T p.R55= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99331043; called by muse, mutect2, varscan2
- NLGN4X | c.762G>T p.G254= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99320145; called by muse, mutect2, varscan2
- NLRP10 | c.1092G>A p.L364= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100149501; called by muse, mutect2, varscan2
- NPAP1 | c.738C>A p.A246= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs753676478, COSV100274843, COSV61507402; called by muse, mutect2, varscan2
- NRXN3 | c.1836G>T p.T612= (on ENST00000557594 / NM_001272020.2; = p.T1036= on NM_004796.6) | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs1417043829, COSV55315254, COSV99816298; called by muse, mutect2, varscan2
- ODF2L | c.6G>A p.E2= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99643861; called by muse, mutect2
- OPRK1 | c.1026G>A p.R342= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55569419; called by muse, mutect2, varscan2
- OR13C8 | c.405C>A p.I135= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100622935, COSV58610772; called by muse, mutect2, varscan2
- OR13C9 | c.429C>A p.P143= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV52241301; called by muse, mutect2, varscan2
- OR2T27 | c.516G>T p.R172= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100788124; called by mutect2, varscan2
- OR2T35 | c.783G>T p.L261= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1374659283; called by muse, varscan2
- OR2Y1 | c.618G>T p.V206= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs200262624, COSV100322671; called by muse, mutect2, varscan2
- OR52E2 | c.660G>T p.V220= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1450415881, COSV100384668, COSV58612709; called by muse, mutect2, varscan2
- OR5H6 | c.831C>T p.G277= (on ENST00000642105; = p.G261= on NM_001005479.2) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs772448858, COSV101051745; called by muse, mutect2, varscan2
- OR5K3 | c.441A>C p.G147= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV101051615; called by muse, mutect2, varscan2
- OR5W2 | c.147C>T p.I49= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100747552, COSV60619159; called by muse, varscan2
- OR8A1 | c.279C>T p.S93= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs886088975, COSV99420351; called by muse, mutect2, varscan2
- PAEP | c.141C>T p.I47= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99478859; called by muse, mutect2
- PATL1 | c.1113G>A p.Q371= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55688977; called by muse, mutect2, varscan2
- PCNX4 | c.496C>T p.L166= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV100469969; called by muse, mutect2, varscan2
- PCNX4 | c.804C>G p.L268= (on ENST00000406854 / NM_001330177.2; = p.L34= on NM_022495.5) | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100469972; called by muse, mutect2, varscan2
- PHF21B | c.441G>T p.G147= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1241455911, COSV100503563; called by muse, mutect2, varscan2
- POLR1A | c.5079G>T p.L1693= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99807173; called by muse, mutect2, varscan2
- POU3F2 | c.114G>A p.Q38= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1436906107, COSV100098985; called by muse, mutect2
- PPP1R13L | c.774G>T p.A258= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1382384630, COSV62908376, COSV62908910; called by muse, mutect2, varscan2
- PRAM1 | c.492C>A p.A164= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99725275; called by muse, mutect2
- PRAMEF1 | c.1227G>A p.L409= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as COSV100179462; called by muse, mutect2, varscan2
- PTPRT | c.2613G>T p.V871= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100625554; called by muse, mutect2, varscan2
- RAG1 | c.1659G>T p.V553= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100200689; called by muse, mutect2, varscan2
- RCOR1 | c.909A>T p.T303= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99217239; called by muse, mutect2, varscan2
- RNF148 | c.480C>G p.G160= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as COSV100411461; called by muse, varscan2
- RNF213 | c.11901G>T p.T3967= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100299819, COSV60404161; called by muse, mutect2, varscan2
- RRP12 | c.867C>T p.I289= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100212945; called by muse, mutect2, varscan2
- RXRG | c.186C>A p.P62= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100717258; called by muse, mutect2
- SAGE1 | c.1782C>A p.S594= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV100186754, COSV61012539; called by muse, mutect2, varscan2
- SAMD15 | c.891T>A p.T297= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs748776915, COSV99374788; called by muse, mutect2, varscan2
- SCN5A | c.1749T>A p.P583= | Silent (SNP) | VAF 84/115 reads (73%) | catalogued as COSV100346749; called by muse, mutect2, varscan2
- SDR9C7 | c.270C>A p.A90= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1439116800, COSV99524515; called by muse, mutect2, varscan2
- SDSL | c.915G>T p.V305= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV100615188; called by muse, mutect2, varscan2
- SFMBT2 | c.1386C>T p.F462= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100738485; called by muse, mutect2, varscan2
- SFSWAP | c.960G>T p.V320= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99905821; called by muse, mutect2, varscan2
- SFSWAP | c.1896A>T p.V632= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99905824; called by muse, mutect2, varscan2
- SIPA1L2 | c.288G>A p.K96= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV99477314; called by muse, mutect2, varscan2
- SLC23A2 | c.1419G>T p.G473= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100594813; called by muse, mutect2, varscan2
- SRRM4 | c.1425G>T p.S475= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99937842; called by muse, mutect2
- SRSF1 | c.18G>C p.V6= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99365229; called by muse, mutect2, varscan2
- SYT16 | c.1615C>A p.R539= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs759960875, COSV101413520, COSV70854773; called by muse, mutect2, varscan2
- TACR3 | c.1230A>T p.T410= | Silent (SNP) | VAF 90/150 reads (60%) | catalogued as rs886058973, COSV100510133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX5 | c.942C>A p.P314= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100090643; called by muse, mutect2, varscan2
- TDRD3 | c.198G>A p.E66= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99539837; called by muse, mutect2, varscan2
- TERF1 | c.465G>C p.L155= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99400978; called by muse, mutect2
- TLN1 | c.1671G>T p.V557= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV100147373; called by muse, mutect2, varscan2
- TMED3 | c.477G>T p.T159= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV100229913, COSV100230002; called by muse, mutect2, varscan2
- TNPO2 | c.2418G>T p.T806= (on ENST00000425528 / NM_001382240.1; = p.T796= on NM_013433.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1371092952, COSV100790287; called by muse, mutect2, varscan2
- USH1G | c.1359G>T p.P453= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1328237495, COSV100140339; called by muse, mutect2, varscan2
- UTP14A | c.1896C>T p.G632= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV64086575; called by muse, mutect2, varscan2
- VCAN | c.1077C>G p.L359= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV54104455, COSV99424865; called by muse, mutect2, varscan2
- ZC3H18 | c.87G>C p.L29= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99963881; called by muse, mutect2, varscan2
- ZFC3H1 | c.4383G>A p.L1461= | Silent (SNP) | VAF 61/244 reads (25%) | catalogued as rs1267851847, COSV101110351; called by muse, mutect2, varscan2
- ZNF695 | c.204G>C p.L68= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100377275; called by muse, mutect2, varscan2
- ZNF875 | c.1512A>G p.R504= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100183117; called by muse, mutect2, varscan2
20 further variants in this file (0 protein-altering or splice-affecting, 1 silent, 19 other) are not listed here.
